Somatic mutation profile of tumor specimen TCGA-CV-5970-01A (aliquot TCGA-CV-5970-01A-11D-1683-08) from TCGA case TCGA-CV-5970, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Tongue, NOS; AJCC pathologic stage: Stage IVA; Tumor grade: G2; Age at diagnosis: 59.9 years (21,890 days).
Specimen TCGA-CV-5970-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c043556e-cf36-4387-b46d-e6e786269469.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CV-5970-10A (Blood Derived Normal), aliquot TCGA-CV-5970-10A-01D-1870-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f76c748f-0d68-4263-8dec-d220f11ed486

The open-access MAF lists 188 somatic variants for this specimen: 134 protein-altering or splice-affecting, 49 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 121, Silent 49, Nonsense Mutation 9, RNA 2, Splice Site 2, Frame Shift Del 1, 3'Flank 1, Intron 1, 3'UTR 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- COL2A1 | c.4316C>T p.T1439M | Missense Mutation (SNP) | VAF 8/70 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.664); catalogued as rs121912886, CM014699, COSV61527816; ClinVar: likely pathogenic / uncertain significance; called by muse, mutect2, varscan2
- ADARB1 | c.406G>A p.E136K | Missense Mutation (SNP) | VAF 10/57 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); catalogued as COSV100654158; called by muse, mutect2, varscan2
- AK5 | c.758G>C p.R253T (on ENST00000354567 / NM_174858.3; = p.R227T on NM_012093.4) | Missense Mutation (SNP) | VAF 12/98 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV100643474, COSV60979537; called by muse, mutect2, varscan2
- ANKRD34A | c.343C>G p.L115V | Missense Mutation (SNP) | VAF 9/48 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100041434; called by muse, varscan2
- ANKRD34A | c.284C>T p.S95L | Missense Mutation (SNP) | VAF 10/60 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.045); catalogued as COSV60160409, COSV60160521; called by muse, varscan2
- ARHGEF17 | c.4857G>T p.M1619I | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT tolerated (0.06); PolyPhen benign (0.001); catalogued as COSV55230634, COSV99736993; called by muse, mutect2, varscan2
- ASXL3 | c.5704C>G p.P1902A | Missense Mutation (SNP) | VAF 6/116 reads (5%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.994); catalogued as COSV99326920; called by muse, mutect2
- ATP6V1E2 | c.58G>C p.E20Q | Missense Mutation (SNP) | VAF 10/66 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.906); catalogued as rs746928461, COSV100120841; called by muse, mutect2, varscan2
- BCL2L14 | c.108C>G p.F36L | Missense Mutation (SNP) | VAF 13/52 reads (25%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.994); catalogued as COSV99845288; called by muse, mutect2, varscan2
- BPIFA3 | c.536+1G>T p.X179_splice | Splice Site (SNP) | VAF 9/109 reads (8%) | catalogued as COSV100967139; called by muse, mutect2
- BRS3 | c.776C>T p.A259V | Missense Mutation (SNP) | VAF 3/49 reads (6%) | SIFT tolerated (0.48); PolyPhen benign (0.012); catalogued as rs1474161520, COSV101036681; called by muse, mutect2
- C19orf47 | c.274G>A p.V92M | Missense Mutation (SNP) | VAF 6/52 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as rs374413956; called by muse, mutect2, varscan2
- C7orf31 | c.1679C>T p.S560L | Missense Mutation (SNP) | VAF 17/107 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.723); catalogued as COSV99384218; called by muse, mutect2, varscan2
- CAD | c.5513G>A p.R1838H | Missense Mutation (SNP) | VAF 19/155 reads (12%) | SIFT tolerated (0.06); PolyPhen benign (0.288); catalogued as rs199572743, COSV53030438, COSV99255928; called by muse, mutect2, varscan2
- CCDC89 | c.938G>A p.R313Q | Missense Mutation (SNP) | VAF 16/70 reads (23%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.558); catalogued as rs570614928, COSV100320928, COSV57034716; called by muse, mutect2, varscan2
- CCL2 | c.178C>A p.P60T | Missense Mutation (SNP) | VAF 15/49 reads (31%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.718); catalogued as COSV99861598; called by muse, mutect2, varscan2
- CCT6A | c.559G>C p.D187H | Missense Mutation (SNP) | VAF 10/86 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV51904596; called by muse, mutect2, varscan2
- CENPA | c.115C>T p.Q39* | Nonsense Mutation (SNP) | VAF 8/25 reads (32%) | catalogued as COSV99273293; called by muse, mutect2, varscan2
- CHD7 | c.6025G>A p.E2009K | Missense Mutation (SNP) | VAF 9/33 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.715); catalogued as rs1334324535, COSV101418516; called by muse, mutect2, varscan2
- CNGB1 | c.94G>C p.E32Q | Missense Mutation (SNP) | VAF 11/60 reads (18%) | SIFT tolerated, low confidence (0.1); PolyPhen possibly damaging (0.601); catalogued as COSV99212267; called by muse, mutect2, varscan2
- COG5 | c.610G>A p.A204T | Missense Mutation (SNP) | VAF 18/72 reads (25%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.639); catalogued as rs1226680404, COSV99773429; called by muse, mutect2, varscan2
- COMMD7 | c.541C>G p.Q181E | Missense Mutation (SNP) | VAF 8/60 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0.086); catalogued as COSV54070914, COSV99640835; called by muse, mutect2, varscan2
- COPB1 | c.2068C>T p.Q690* | Nonsense Mutation (SNP) | VAF 18/179 reads (10%) | catalogued as COSV99999977; called by muse, mutect2, varscan2
- CPLANE1 | c.9355C>T p.P3119S | Missense Mutation (SNP) | VAF 7/103 reads (7%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.457); catalogued as COSV99951956; called by muse, mutect2
- CRACR2A | c.1079G>A p.R360H | Missense Mutation (SNP) | VAF 7/43 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs773874892, COSV99365584; called by muse, mutect2, varscan2
- CRB1 | c.2146T>C p.F716L | Missense Mutation (SNP) | VAF 7/44 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV100958058, COSV66330407; called by muse, mutect2, varscan2
- CTTN | c.1646G>A p.R549Q | Missense Mutation (SNP) | VAF 12/52 reads (23%) | SIFT tolerated (0.28); PolyPhen probably damaging (0.926); catalogued as rs778284858, COSV100096971; called by muse, mutect2, varscan2
- CXorf58 | c.14C>T p.S5L | Missense Mutation (SNP) | VAF 8/18 reads (44%) | SIFT tolerated, low confidence (0.43); PolyPhen benign (0.007); catalogued as rs1370878886, COSV101003130; called by muse, mutect2, varscan2
- DHRS4 | c.163G>T p.D55Y | Missense Mutation (SNP) | VAF 18/111 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV100366070; called by muse, mutect2, varscan2
- DMGDH | c.1030C>T p.R344* | Nonsense Mutation (SNP) | VAF 14/89 reads (16%) | catalogued as rs143021634, COSV54865650; called by muse, mutect2, varscan2
- DTX3L | c.772G>C p.E258Q | Missense Mutation (SNP) | VAF 3/44 reads (7%) | SIFT tolerated (0.2); PolyPhen benign (0.025); catalogued as COSV99949877, COSV99950172; called by muse, mutect2
- ECT2 | c.330G>A p.M110I (on ENST00000392692 / NM_001349098.2; = p.M79I on NM_018098.6 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 81/203 reads (40%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as COSV99221741; called by muse, mutect2, varscan2
- EFCAB6 | c.1171G>T p.E391* | Nonsense Mutation (SNP) | VAF 23/122 reads (19%) | catalogued as COSV53065302, COSV99414596; called by muse, mutect2, varscan2
- EIF2S2 | c.445G>T p.E149* | Nonsense Mutation (SNP) | VAF 6/43 reads (14%) | catalogued as COSV100895017; called by muse, mutect2, varscan2
- EIF4A3 | c.58G>C p.E20Q | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.003); catalogued as COSV99484241; called by muse, mutect2, varscan2
- EYA4 | c.536C>A p.T179K | Missense Mutation (SNP) | VAF 9/66 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.457); catalogued as COSV100766465; called by muse, mutect2, varscan2
- FRAS1 | c.11303G>A p.R3768H | Missense Mutation (SNP) | VAF 15/90 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs867954723, COSV53620184; called by muse, mutect2, varscan2
- GK2 | c.1495C>T p.R499C | Missense Mutation (SNP) | VAF 14/95 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.021); catalogued as rs267600272, COSV62626492; called by muse, mutect2, varscan2
- GOPC | c.982G>A p.G328R | Missense Mutation (SNP) | VAF 35/143 reads (24%) | SIFT tolerated (0.07); PolyPhen benign (0.33); catalogued as rs751358313, COSV99271436; called by muse, mutect2, varscan2
- GPR18 | c.167C>T p.T56M | Missense Mutation (SNP) | VAF 29/90 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.98); catalogued as rs753458670, COSV100540683; called by muse, mutect2, varscan2
- GRID2 | c.1857A>C p.Q619H | Missense Mutation (SNP) | VAF 11/68 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV56259302, COSV99947711; called by muse, mutect2, varscan2
- GRIN2A | c.1342G>A p.E448K | Missense Mutation (SNP) | VAF 16/81 reads (20%) | SIFT tolerated (0.54); PolyPhen benign (0.021); catalogued as rs368026708, COSV58030003; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- GSDMB | c.10G>A p.V4I | Missense Mutation (SNP) | VAF 17/68 reads (25%) | SIFT tolerated (0.46); PolyPhen benign (0.001); catalogued as rs754568783, COSV100401599; called by muse, mutect2
- GSS | c.602C>T p.S201L | Missense Mutation (SNP) | VAF 11/80 reads (14%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.99); catalogued as rs1040178198, COSV99404218; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- HAPLN3 | c.248G>A p.R83H | Missense Mutation (SNP) | VAF 22/85 reads (26%) | SIFT tolerated (0.14); PolyPhen benign (0.035); catalogued as rs1287870721, COSV62086651; called by muse, mutect2, varscan2
- HID1 | c.239G>T p.G80V | Missense Mutation (SNP) | VAF 17/55 reads (31%) | SIFT tolerated (0.35); PolyPhen benign (0.006); catalogued as COSV100586115; called by muse, mutect2, varscan2
- HP1BP3 | c.274G>A p.E92K | Missense Mutation (SNP) | VAF 21/133 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.971); catalogued as COSV100392142; called by muse, mutect2, varscan2
- INTS4 | c.2878C>G p.P960A | Missense Mutation (SNP) | VAF 9/91 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.551); catalogued as rs757466320, COSV100490168; called by muse, mutect2, varscan2
- INTU | c.2078G>A p.R693K | Missense Mutation (SNP) | VAF 19/108 reads (18%) | SIFT tolerated (0.5); PolyPhen benign (0.007); catalogued as COSV100081473; called by muse, mutect2, varscan2
- INTU | c.2224G>A p.E742K | Missense Mutation (SNP) | VAF 25/148 reads (17%) | SIFT tolerated (0.26); PolyPhen benign (0.023); catalogued as COSV100081476; called by muse, mutect2, varscan2
- ISM2 | c.1233G>C p.K411N | Missense Mutation (SNP) | VAF 10/62 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); catalogued as COSV99376922; called by muse, mutect2, varscan2
- JMJD1C | c.459C>G p.D153E | Missense Mutation (SNP) | VAF 18/96 reads (19%) | SIFT tolerated (0.11); PolyPhen benign (0.027); catalogued as COSV101232520; called by muse, mutect2, varscan2
- KASH5 | c.929C>T p.S310F | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.804); catalogued as COSV101483517; called by muse, mutect2, varscan2
- KCNAB1 | c.382G>A p.A128T (on ENST00000490337 / NM_172160.3; = p.A117T on NM_003471.3) | Missense Mutation (SNP) | VAF 20/190 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV56744848; called by muse, mutect2, varscan2
- KYNU | c.1196G>A p.R399Q | Missense Mutation (SNP) | VAF 10/64 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs780204087, COSV51587622; called by muse, mutect2, varscan2
- LNPEP | c.115C>G p.L39V | Missense Mutation (SNP) | VAF 13/92 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.685); catalogued as COSV51480769; called by muse, mutect2, varscan2
- LRRC40 | c.1336G>C p.E446Q | Missense Mutation (SNP) | VAF 7/43 reads (16%) | SIFT tolerated (0.13); PolyPhen benign (0.102); catalogued as COSV100918871; called by muse, mutect2
- LRRIQ1 | c.4779A>C p.K1593N | Missense Mutation (SNP) | VAF 5/78 reads (6%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.966); catalogued as COSV101280742; called by muse, mutect2
- LRRTM3 | c.1591A>C p.S531R | Missense Mutation (SNP) | VAF 14/120 reads (12%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0); catalogued as COSV100791947; called by muse, mutect2
- LSM4 | c.319G>A p.A107T | Missense Mutation (SNP) | VAF 9/57 reads (16%) | SIFT tolerated (0.11); PolyPhen benign (0.001); catalogued as rs1465402545, COSV99416922; called by muse, mutect2, varscan2
- MAP3K13 | c.2569G>C p.D857H | Missense Mutation (SNP) | VAF 16/168 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV53993300, COSV99406449; called by muse, mutect2, varscan2
- MAP6 | c.1354C>T p.Q452* | Nonsense Mutation (SNP) | VAF 16/72 reads (22%) | catalogued as rs375115786; called by muse, mutect2, varscan2
- MAP9 | c.948G>T p.K316N | Missense Mutation (SNP) | VAF 10/66 reads (15%) | SIFT tolerated (0.32); PolyPhen possibly damaging (0.856); catalogued as COSV100251149; called by muse, mutect2, varscan2
- MAST4 | c.1082C>T p.S361F (on ENST00000403625 / NM_001164664.2; = p.S172F on NM_015183.3) | Missense Mutation (SNP) | VAF 16/82 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV99846205; called by muse, mutect2, varscan2
- MED12L | c.1907G>A p.R636Q | Missense Mutation (SNP) | VAF 9/78 reads (12%) | SIFT tolerated (0.58); PolyPhen benign (0.027); catalogued as rs368991764; called by muse, mutect2, varscan2
- MED12L | c.5930C>G p.S1977C | Missense Mutation (SNP) | VAF 13/161 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.993); catalogued as COSV56367908, COSV99854999; called by muse, mutect2
- MSH2 | c.1144C>T p.R382C | Missense Mutation (SNP) | VAF 11/62 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); catalogued as rs752373431, COSV51876239, COSV99254668; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MSLN | c.1808-1G>T p.X603_splice (on ENST00000382862 / NM_013404.4; = p.X595_splice on NM_005823.6) | Splice Site (SNP) | VAF 13/70 reads (19%) | catalogued as COSV53503995, COSV99558868; called by muse, mutect2, varscan2
- MUC4 | c.15190G>A p.G5064R (on ENST00000463781 / NM_018406.7; = p.G828R on NM_004532.6) | Missense Mutation (SNP) | VAF 28/76 reads (37%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.003); catalogued as rs1347114166, COSV100206762, COSV57769537; called by muse, mutect2, varscan2
- MYL7 | c.275C>T p.T92M | Missense Mutation (SNP) | VAF 11/91 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.756); catalogued as rs142668114; called by muse, mutect2, varscan2
- NAALADL1 | c.220C>T p.P74S | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT tolerated (0.27); PolyPhen benign (0.01); catalogued as COSV100368286; called by muse, mutect2
- NAPSA | c.1141T>A p.Y381N | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.559); catalogued as COSV99516022; called by muse, mutect2, varscan2
- NDUFA7 | c.249G>C p.E83D | Missense Mutation (SNP) | VAF 17/113 reads (15%) | SIFT tolerated (0.27); PolyPhen benign (0.005); catalogued as COSV100035678; called by muse, mutect2, varscan2
- NEK9 | c.1972G>A p.G658S | Missense Mutation (SNP) | VAF 23/59 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs151072111; called by muse, mutect2, varscan2
- NELFA | c.1393C>T p.P465S (on ENST00000542778; = p.P454S on NM_005663.5) | Missense Mutation (SNP) | VAF 14/42 reads (33%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.999); catalogued as COSV100374001; called by muse, mutect2, varscan2
- NEMF | c.2498C>G p.S833* | Nonsense Mutation (SNP) | VAF 8/57 reads (14%) | catalogued as COSV100028175; called by muse, mutect2, varscan2
- NFATC3 | c.1616G>C p.G539A | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100285829; called by muse, mutect2, varscan2
- NID1 | c.1941G>T p.K647N | Missense Mutation (SNP) | VAF 43/227 reads (19%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as COSV99938438; called by muse, mutect2, varscan2
- NKD1 | c.92G>A p.R31Q | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.979); catalogued as COSV51693327, COSV99194145; called by muse, mutect2, varscan2
- NTRK3 | c.1592A>G p.Q531R | Missense Mutation (SNP) | VAF 23/110 reads (21%) | SIFT tolerated (0.23); PolyPhen benign (0.02); catalogued as rs757573108, COSV100714019; called by muse, mutect2, varscan2
- NUCB1 | c.988G>A p.G330R | Missense Mutation (SNP) | VAF 8/51 reads (16%) | SIFT tolerated (0.1); PolyPhen benign (0.026); catalogued as rs1391084512, COSV99618187; called by muse, mutect2, varscan2
- OR4A15 | c.363C>A p.Y121* | Nonsense Mutation (SNP) | VAF 36/196 reads (18%) | catalogued as rs199792741, COSV100124390; called by muse, mutect2, varscan2
- OR5AS1 | c.475C>T p.H159Y | Missense Mutation (SNP) | VAF 71/188 reads (38%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.666); catalogued as rs868571597, COSV100546420, COSV57982766; called by muse, mutect2, varscan2
- PCID2 | c.1145A>T p.Q382L | Missense Mutation (SNP) | VAF 27/57 reads (47%) | SIFT deleterious (0.01); PolyPhen benign (0.41); catalogued as COSV99872714; called by muse, mutect2, varscan2
- PI4KA | c.4196G>C p.R1399P | Missense Mutation (SNP) | VAF 5/50 reads (10%) | SIFT tolerated (0.1); PolyPhen benign (0.125); catalogued as COSV99748965; called by mutect2, varscan2
- PIK3C2B | c.3439G>A p.V1147M | Missense Mutation (SNP) | VAF 10/31 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100916239; called by muse, mutect2, varscan2
- PITRM1 | c.2274C>G p.I758M | Missense Mutation (SNP) | VAF 10/67 reads (15%) | SIFT tolerated (0.23); PolyPhen benign (0.055); catalogued as COSV99829760; called by muse, mutect2, varscan2
- PLA2R1 | c.4103C>T p.P1368L | Missense Mutation (SNP) | VAF 13/116 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.676); catalogued as rs767770232, COSV51787669; called by muse, mutect2, varscan2
- PPP1R26 | c.370G>C p.D124H | Missense Mutation (SNP) | VAF 79/134 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100778171; called by muse, mutect2, varscan2
- PRAME | c.356T>G p.L119R | Missense Mutation (SNP) | VAF 11/79 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101287280; called by muse, mutect2
- PSMD1 | c.1426G>A p.G476S | Missense Mutation (SNP) | VAF 5/36 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV58077802; called by muse, mutect2, varscan2
- RABL3 | c.316T>G p.L106V | Missense Mutation (SNP) | VAF 10/53 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1407548864, COSV99846672; called by muse, mutect2, varscan2
- RFPL2 | c.901C>T p.R301C | Missense Mutation (SNP) | VAF 14/59 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.86); catalogued as rs755080826, COSV99964084, COSV99964676; called by muse, mutect2, varscan2
- RPS6KB1 | c.217G>A p.E73K | Missense Mutation (SNP) | VAF 17/137 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.093); catalogued as COSV56677844; called by muse, mutect2, varscan2
- SCML2 | c.824T>C p.L275S | Missense Mutation (SNP) | VAF 13/42 reads (31%) | SIFT tolerated (0.7); PolyPhen benign (0.009); catalogued as COSV99319558; called by muse, mutect2, varscan2
- SCN1A | c.4325T>C p.V1442A (on ENST00000303395 / NM_001202435.3; = p.V1431A on NM_006920.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 15/115 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.661); catalogued as COSV57658712; called by muse, mutect2, varscan2
- SEMA5A | c.1876A>G p.T626A | Missense Mutation (SNP) | VAF 9/52 reads (17%) | SIFT tolerated (1); PolyPhen benign (0.015); catalogued as COSV101228753; called by muse, mutect2, varscan2
- SEMG1 | c.805C>G p.Q269E | Missense Mutation (SNP) | VAF 9/82 reads (11%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.848); catalogued as COSV99725609; called by muse, mutect2
- SETBP1 | c.685G>T p.G229* | Nonsense Mutation (SNP) | VAF 8/54 reads (15%) | catalogued as COSV99955247; called by muse, mutect2, varscan2
- SFMBT2 | c.344G>A p.R115H | Missense Mutation (SNP) | VAF 8/45 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs868013820, COSV62808092; called by muse, mutect2, varscan2
- SFTPC | c.38C>T p.P13L | Missense Mutation (SNP) | VAF 14/71 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV100110215; called by muse, mutect2
- SHROOM2 | c.1321G>A p.D441N | Missense Mutation (SNP) | VAF 20/38 reads (53%) | SIFT tolerated (0.82); PolyPhen benign (0.001); catalogued as COSV101099129; called by muse, mutect2, varscan2
- SLC30A3 | c.637G>A p.E213K | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT tolerated (0.34); PolyPhen benign (0.038); catalogued as COSV99273943; called by muse, mutect2, varscan2
- SLC35A5 | c.1054G>C p.D352H | Missense Mutation (SNP) | VAF 13/109 reads (12%) | SIFT tolerated (0.1); PolyPhen benign (0.346); catalogued as COSV99656936; called by muse, mutect2, varscan2
- SLC39A14 | c.448G>A p.A150T | Missense Mutation (SNP) | VAF 4/23 reads (17%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as rs757888834, COSV99249844; called by muse, mutect2, varscan2
- SRRM1 | c.772G>C p.E258Q | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.968); catalogued as COSV100105247, COSV60479141; called by muse, mutect2
- STARD3NL | c.593T>G p.L198R | Missense Mutation (SNP) | VAF 9/111 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.305); catalogued as COSV99151613; called by muse, mutect2
- STRN | c.2050G>A p.E684K | Missense Mutation (SNP) | VAF 16/90 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as rs763412654, COSV99815776; called by muse, mutect2, varscan2
- SYCE2 | c.63G>T p.L21F | Missense Mutation (SNP) | VAF 14/61 reads (23%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.295); catalogued as COSV99536220; called by muse, mutect2, varscan2
- SYNM | c.4340C>T p.T1447M | Missense Mutation (SNP) | VAF 34/156 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.036); catalogued as rs781787123, COSV50440761, COSV50443415; called by muse, mutect2, varscan2
- TAB1 | c.1372G>A p.D458N | Missense Mutation (SNP) | VAF 11/108 reads (10%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.977); catalogued as COSV99336326; called by muse, mutect2, varscan2
- TAF9 | c.751G>A p.D251N | Missense Mutation (SNP) | VAF 7/56 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.058); catalogued as COSV99472806; called by muse, mutect2, varscan2
- TARDBP | c.556G>C p.E186Q | Missense Mutation (SNP) | VAF 11/90 reads (12%) | SIFT tolerated (0.42); PolyPhen benign (0.054); catalogued as COSV53569528, COSV99534504; called by muse, mutect2, varscan2
- TARS1 | c.169C>T p.R57C | Missense Mutation (SNP) | VAF 10/112 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99465703; called by muse, mutect2
- TMEM258 | c.67G>A p.V23M | Missense Mutation (SNP) | VAF 8/23 reads (35%) | SIFT tolerated (0.29); PolyPhen benign (0.058); catalogued as rs764740554, COSV99607990; called by muse, mutect2, varscan2
- TMEM260 | c.1731T>G p.D577E | Missense Mutation (SNP) | VAF 21/90 reads (23%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as COSV99840746; called by muse, mutect2, varscan2
- TPI1 | c.787G>A p.D263N (on ENST00000229270; = p.D226N on NM_000365.6) | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.805); catalogued as COSV99222999; called by muse, mutect2, varscan2
- TTC1 | c.14C>T p.S5L | Missense Mutation (SNP) | VAF 8/60 reads (13%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.039); catalogued as COSV99180668; called by muse, mutect2, varscan2
- TTN | c.93909G>C p.W31303C (on ENST00000591111; = p.W23879C on NM_003319.4) | Missense Mutation (SNP) | VAF 10/74 reads (14%) | PolyPhen probably damaging (0.999); catalogued as COSV100633469, COSV100635271; called by muse, mutect2, varscan2
- TTN | c.81025T>C p.F27009L (on ENST00000591111; = p.F19585L on NM_003319.4) | Missense Mutation (SNP) | VAF 21/104 reads (20%) | PolyPhen probably damaging (0.987); catalogued as COSV104413445, COSV60185332; called by muse, mutect2, varscan2
- UBE3B | c.3166C>T p.R1056C | Missense Mutation (SNP) | VAF 10/64 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1015920433, COSV61073477; called by muse, mutect2, varscan2
- VEZT | c.2311G>C p.E771Q | Missense Mutation (SNP) | VAF 4/27 reads (15%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.154); catalogued as COSV99704375; called by muse, mutect2, varscan2
- VWF | c.3049G>A p.D1017N | Missense Mutation (SNP) | VAF 13/80 reads (16%) | SIFT tolerated (0.08); PolyPhen benign (0.012); catalogued as rs751031390, COSV99780431; called by muse, mutect2, varscan2
- WFDC1 | c.481G>A p.E161K | Missense Mutation (SNP) | VAF 15/54 reads (28%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.572); catalogued as COSV54744133, COSV99550910; called by muse, mutect2, varscan2
- WNT16 | c.811G>C p.E271Q (on ENST00000222462 / NM_057168.2; = p.E261Q on NM_016087.2) | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT tolerated (0.31); PolyPhen benign (0.104); catalogued as COSV99743471; called by muse, mutect2
- XKR4 | c.1824G>C p.E608D | Missense Mutation (SNP) | VAF 7/35 reads (20%) | SIFT tolerated (1); PolyPhen benign (0.211); catalogued as COSV100534263; called by muse, mutect2, varscan2
- ZNF232 | c.1301G>A p.R434Q | Missense Mutation (SNP) | VAF 19/99 reads (19%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs200981387; called by muse, mutect2, varscan2
- ZNF292 | c.2881G>A p.G961S | Missense Mutation (SNP) | VAF 18/69 reads (26%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.003); catalogued as COSV100371467; called by muse, mutect2, varscan2
- ZNF592 | c.1209G>C p.K403N | Missense Mutation (SNP) | VAF 8/41 reads (20%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.905); catalogued as COSV100246163; called by muse, mutect2, varscan2
- ZNF653 | c.1030G>A p.G344S | Missense Mutation (SNP) | VAF 29/54 reads (54%) | SIFT tolerated (0.62); PolyPhen benign (0.023); catalogued as rs755454639, COSV53402252, COSV53402304; called by muse, mutect2, varscan2
- HGH1 | c.687C>G p.F229L | Missense Mutation (SNP) | VAF 3/31 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.873); called by muse, mutect2
- PRICKLE1 | c.2099_2113del p.R700_Y704del | In Frame Del (DEL) | VAF 13/90 reads (14%) | called by mutect2, pindel
- SBF1 | c.3519G>C p.Q1173H | Missense Mutation (SNP) | VAF 4/46 reads (9%) | SIFT tolerated (0.08); PolyPhen benign (0.009); called by muse, mutect2
- TARBP1 | c.2675_2690del p.Q892Lfs*4 | Frame Shift Del (DEL) | VAF 12/74 reads (16%) | called by mutect2, pindel, varscan2
- AFF2 | c.1179G>A p.S393= | Silent (SNP) | VAF 45/70 reads (64%) | catalogued as rs149177157, COSV99666696; called by muse, mutect2, varscan2
- ASXL2 | c.993C>T p.F331= | Silent (SNP) | VAF 13/96 reads (14%) | catalogued as COSV55454364, COSV99712155; called by muse, mutect2, varscan2
- ATG2A | c.1233G>A p.K411= | Silent (SNP) | VAF 29/80 reads (36%) | catalogued as COSV101034881; called by muse, mutect2, varscan2
- BMP7 | c.666C>T p.G222= | Silent (SNP) | VAF 10/51 reads (20%) | catalogued as COSV101216332; called by muse, mutect2, varscan2
- C4orf50 | c.813G>A p.P271= (on ENST00000324058; = p.P1503= on NM_001364689.1 and 1 other RefSeq transcript) | Silent (SNP) | VAF 16/122 reads (13%) | catalogued as rs368880548; called by muse, mutect2, varscan2
- CAV3 | c.291C>T p.F97= | Silent (SNP) | VAF 4/20 reads (20%) | catalogued as COSV57481735; called by muse, mutect2, varscan2
- CCDC68 | c.963C>T p.T321= | Silent (SNP) | VAF 7/31 reads (23%) | catalogued as rs775229151, COSV100492065; called by muse, mutect2, varscan2
- CDCP2 | c.333G>C p.P111= | Silent (SNP) | VAF 10/45 reads (22%) | catalogued as COSV100313725; called by muse, mutect2, varscan2
- CDH11 | c.264T>C p.I88= | Silent (SNP) | VAF 8/48 reads (17%) | catalogued as COSV99218722; called by muse, mutect2, varscan2
- CFAP206 | c.498G>A p.Q166= | Silent (SNP) | VAF 27/39 reads (69%) | catalogued as COSV51536598, COSV99740194; called by muse, mutect2, varscan2
- CPNE6 | c.1266G>A p.P422= | Silent (SNP) | VAF 5/33 reads (15%) | catalogued as rs779770775, COSV53745543; called by muse, mutect2, varscan2
- DEF8 | c.162G>A p.T54= | Silent (SNP) | VAF 11/61 reads (18%) | catalogued as rs1349411659, COSV99240807; called by muse, mutect2, varscan2
- ERICH6 | c.1746G>A p.E582= | Silent (SNP) | VAF 11/151 reads (7%) | catalogued as rs777085377, COSV55802012; called by muse, mutect2
- FCN2 | c.885G>A p.S295= | Silent (SNP) | VAF 48/67 reads (72%) | catalogued as rs150154280; called by muse, mutect2, varscan2
- FOXL1 | c.213G>A p.T71= | Silent (SNP) | VAF 28/105 reads (27%) | catalogued as rs1194655178, COSV100206449; called by muse, mutect2, varscan2
- GRM5 | c.1051C>A p.R351= | Silent (SNP) | VAF 12/47 reads (26%) | catalogued as rs746488178, COSV59603338, COSV59609677; called by muse, mutect2
- HAPLN4 | c.24C>T p.L8= | Silent (SNP) | VAF 4/14 reads (29%) | catalogued as COSV99364076; called by muse, mutect2
- HIF3A | c.1506C>G p.L502= (on ENST00000377670 / NM_152795.4; = p.L433= on NM_022462.4) | Silent (SNP) | VAF 18/103 reads (17%) | catalogued as COSV99356112; called by muse, mutect2, varscan2
- HSCB | c.303C>T p.V101= | Silent (SNP) | VAF 16/122 reads (13%) | catalogued as COSV99319796; called by muse, mutect2, varscan2
- ITPRIP | c.771C>T p.C257= | Silent (SNP) | VAF 27/84 reads (32%) | catalogued as rs200546667; called by muse, mutect2, varscan2
- KRT79 | c.111G>A p.T37= | Silent (SNP) | VAF 8/70 reads (11%) | catalogued as rs373619417; called by mutect2, varscan2
- LIMA1 | c.378C>T p.P126= | Silent (SNP) | VAF 13/78 reads (17%) | catalogued as COSV100372750; called by muse, mutect2, varscan2
- LRP2 | c.3312C>T p.H1104= | Silent (SNP) | VAF 17/122 reads (14%) | catalogued as rs188152163, COSV55554081; called by muse, mutect2, varscan2
- LRP5 | c.810G>A p.K270= | Silent (SNP) | VAF 7/85 reads (8%) | catalogued as COSV99592726; called by muse, mutect2
- LRRTM1 | c.792G>C p.S264= | Silent (SNP) | VAF 8/54 reads (15%) | catalogued as COSV54440145, COSV99703327; called by muse, mutect2, varscan2
- LRRTM1 | c.678C>T p.F226= | Silent (SNP) | VAF 21/119 reads (18%) | catalogued as rs1458764773, COSV99703331; called by muse, mutect2, varscan2
- MARCHF6 | c.1479G>A p.L493= | Silent (SNP) | VAF 30/370 reads (8%) | catalogued as COSV99930224; called by muse, mutect2
- MBD3 | c.588C>G p.L196= | Silent (SNP) | VAF 6/22 reads (27%) | catalogued as rs376503261; called by muse, mutect2, varscan2
- MMP24 | c.1797C>T p.S599= | Silent (SNP) | VAF 20/137 reads (15%) | catalogued as rs779868110, COSV55771754; called by muse, mutect2
- MUC1 | c.3423G>A p.L1141= (on ENST00000611571 / NM_001371720.1; = p.L152= on NM_002456.6 and 1 other RefSeq transcript) | Silent (SNP) | VAF 7/32 reads (22%) | catalogued as COSV100104921; called by muse, mutect2, varscan2
- NAV3 | c.4569T>G p.S1523= | Silent (SNP) | VAF 9/60 reads (15%) | catalogued as COSV99896394; called by muse, mutect2, varscan2
- NRDE2 | c.1839A>G p.R613= | Silent (SNP) | VAF 22/130 reads (17%) | catalogued as COSV100583687; called by muse, varscan2
- PACSIN1 | c.1182C>T p.Y394= | Silent (SNP) | VAF 31/182 reads (17%) | catalogued as rs1364430542, COSV99763387; called by muse, mutect2, varscan2
- PCDHGB4 | c.1572C>T p.R524= | Silent (SNP) | VAF 22/62 reads (35%) | catalogued as COSV53905136, COSV99545441; called by muse, varscan2
- PPFIBP1 | c.2559G>A p.L853= (on ENST00000318304 / NM_177444.3; = p.L847= on NM_003622.4) | Silent (SNP) | VAF 11/87 reads (13%) | catalogued as COSV99945568; called by muse, mutect2, varscan2
- PRKDC | c.4608G>A p.A1536= | Silent (SNP) | VAF 17/40 reads (43%) | catalogued as rs371799969, COSV58041494; called by muse, mutect2, varscan2
- RAMP1 | c.150C>A p.A50= | Silent (SNP) | VAF 21/94 reads (22%) | catalogued as COSV99614988; called by muse, mutect2, varscan2
- RPLP0 | c.429C>T p.I143= | Silent (SNP) | VAF 4/40 reads (10%) | catalogued as rs553386311, COSV56107650; called by mutect2, varscan2
- RPTOR | c.3987G>A p.S1329= | Silent (SNP) | VAF 21/66 reads (32%) | catalogued as rs769703866, COSV60803408; called by muse, mutect2, varscan2
- SDK1 | c.5865G>A p.P1955= | Silent (SNP) | VAF 10/60 reads (17%) | catalogued as rs144472783; called by mutect2, varscan2
- SH2B1 | c.1647C>T p.H549= | Silent (SNP) | VAF 11/59 reads (19%) | catalogued as rs1009035749, COSV100451304; called by muse, mutect2
- SLC1A3 | c.1506G>A p.L502= | Silent (SNP) | VAF 22/250 reads (9%) | catalogued as COSV99468472; called by muse, mutect2
- SNED1 | c.1368C>T p.P456= | Silent (SNP) | VAF 5/15 reads (33%) | catalogued as rs377147382; called by muse, varscan2
- ST3GAL3 | c.333G>A p.T111= (on ENST00000361392 / NM_174964.4; = p.T96= on NM_006279.5) | Silent (SNP) | VAF 29/210 reads (14%) | catalogued as rs763879713, COSV99496090; called by muse, mutect2, varscan2
- TIE1 | c.1953C>T p.H651= | Silent (SNP) | VAF 6/57 reads (11%) | catalogued as rs749033729, COSV100992225; called by muse, mutect2, varscan2
- TMPRSS2 | c.303C>T p.A101= | Silent (SNP) | VAF 16/53 reads (30%) | catalogued as rs745767347, COSV100152251; called by muse, mutect2, varscan2
- TNFSF14 | c.63C>T p.F21= | Silent (SNP) | VAF 21/120 reads (18%) | catalogued as COSV99838570; called by muse, mutect2, varscan2
- TRPM1 | c.3798C>T p.S1266= | Silent (SNP) | VAF 14/74 reads (19%) | catalogued as rs1566982344, COSV56642199; called by muse, mutect2, varscan2
- ZNF667 | c.1105C>A p.R369= | Silent (SNP) | VAF 26/51 reads (51%) | catalogued as rs760367829, COSV52636205, COSV99411055; called by muse, mutect2, varscan2
- COPS9 | chr2:240126762 C>T | 3'Flank (SNP) | VAF 18/144 reads (13%) | catalogued as rs140948790; called by muse, mutect2, varscan2
- EIF4A2 | c.208+125C>T | Intron (SNP) | VAF 10/124 reads (8%) | catalogued as COSV100125674; called by muse, mutect2
- FAM27E5 | n.229G>A | RNA (SNP) | VAF 17/62 reads (27%) | catalogued as rs747263051; called by muse, mutect2, varscan2
- NDST1 | c.*2C>T | 3'UTR (SNP) | VAF 28/278 reads (10%) | catalogued as rs770646949, COSV99939123; called by muse, mutect2
- SNORD113-7 | n.21G>A | RNA (SNP) | VAF 20/72 reads (28%) | catalogued as rs779633314; called by muse, mutect2, varscan2
